Surgical pathology report (de-identified scan), TCGA case TCGA-SA-A6C2, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site  ABS - IUPUI, specimen TCGA-SA-A6C2-01A (Primary Tumor).

[page 1 of 2]
Specimen Received:

Peri aortic mass and left colon

Final Pathologic Diagnosis:

Periaortic mass and left colon, excision and partial colectomy:

Paraganglioma (6.4 cm). See Note.

Segment of colon with no significant histological change.

Twelve lymph nodes, negative for malignancy (0/13).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

The lesion shows a Zellballen pattern. Immunostains were performed to further characterize this lesion. Atypical cells are positive for synaptophysin, chromogranin and Melanin A. They are negative for MITF, HMB45, and Cam 5.2. S100 fails to highlight sustentacular cells. These findings support the above diagnosis.

Gross Description:

The specimen is received without fixative for tissue procurement labeled with the patient's name, and labeled "periaortic mass and left colon" and consists of a short segment of colon received with some associated fat. The colon is received previously opened in a longitudinal fashion. The colon has a length of 4.6 cm and a diameter of 2.7 cm. Loosely attached to the associated fat is a previously inked and incised gray-tan, lobulated mass, which has dimensions of 6.4 x 3.8 x 2.2 cm. There are numerous staples present on the external surface of the mass. Additionally, loosely attached to the mass is a sutured tubular structure, which has a length of 1.6 cm and a diameter of approximately 0.6 cm throughout. The mass is further sectioned to reveal a red-brown, focally myxoid glistening cut surface. This mass does not invade the attached tubular structure or the colon. The tubular structure is further sectioned to reveal a double barreled lumen. It is unclear as to whether this structure represents a vessel or possible ureter.

The serosa of the colon is gray-tan, smooth and glistening to somewhat granular. The lumen contains a small amount of red-brown, mucoid fluid. The mucosa is gray-tan with the usual folds. The wall thickness is approximately 0.4 cm throughout. Sectioning through the associated fat reveals 13 probable lymph nodes that range from 0.1 to 0.4 cm in greatest dimension.

Representative sections are submitted as labeled:

- 1 opposing margins from the tubular structure;
- 2-5 mass to include adjacent tubular structure;
- 6-7 opposing colonic margins;

[page 2 of 2]
8 central longitudinal sections of colon;
9-11 13 probable lymph nodes submitted in toto.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken:

Gender: F

Source: NCI Genomic Data Commons file 1386261f-a832-4c18-833e-1de7984edb9b (TCGA-SA-A6C2.AFC4E0ED-6392-43B5-9493-E4167CD47D41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).